CCDI case PBCMVF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a93cf29d-b2bd-4ab8-acdb-dfa1cc4d9483

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neuroepithelioma, NOS: ICD-O-3 morphology code: 9503/3; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 17.2 years (6,298 days).

Biospecimens (3 samples)
- Sample 0DVLZJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVM1N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVM1R: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
